Somatic mutation profile of tumor specimen TCGA-EL-A4K6-01A (aliquot TCGA-EL-A4K6-01A-12D-A257-08) from TCGA case TCGA-EL-A4K6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.1 years (27,416 days).
Specimen TCGA-EL-A4K6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 902bc91c-7df5-4778-bdfe-eee7f4ad4773.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K6-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K6-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a66420b-5bdb-4d5d-a3c5-3f75b15cceec

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 87/198 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TTN | c.45373C>T p.R15125* (on ENST00000591111; = p.R7701* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs754866489, COSV59917424; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNND2 | c.2036T>C p.L679P | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58907304; called by muse, mutect2
- FCRL2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1387548192, COSV63834361, COSV63835621; called by muse, mutect2, varscan2
- ITPRID1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs750792790, COSV60074268; called by muse, mutect2
- LRRC3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1289907108, COSV52399195; called by muse, mutect2, varscan2
- PFKFB4 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 42/82 reads (51%) | PolyPhen probably damaging (1); catalogued as COSV51681941; called by muse, mutect2, varscan2
- PITX2 | c.668C>G p.S223W (on ENST00000354925 / NM_001204397.1; = p.S230W on NM_000325.6) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60740732, COSV60741667; called by muse, mutect2, varscan2
- PRKDC | c.12263A>G p.N4088S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV58058465; called by muse, mutect2, varscan2
- RAP1A | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV62728423; called by muse, mutect2, varscan2
- SCN11A | c.4379C>T p.T1460M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs762273242, COSV56574172; called by muse, mutect2, varscan2
- SH3PXD2A | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as COSV60118689; called by muse, mutect2, varscan2
- SHANK2 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1555154146, COSV53609336; called by muse, mutect2, varscan2
- ZNF2 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs774098628, COSV54637668; called by muse, mutect2, varscan2
- SLA | c.645_646del p.N216Pfs*26 (on ENST00000338087 / NM_001045556.3; = p.N256Pfs*26 on NM_006748.4) | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by pindel, varscan2
- TIMMDC1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ADCY1 | c.1074G>A p.S358= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs754027303, COSV52038710, COSV99812241; called by muse, mutect2, varscan2
- C12orf71 | c.573C>T p.I191= | Silent (SNP) | VAF 59/114 reads (52%) | catalogued as COSV70282810; called by muse, mutect2, varscan2
- DIS3 | c.1590G>A p.V530= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs934680237, COSV66707290; called by muse, mutect2
- FBXO11 | c.549T>C p.C183= (on ENST00000403359 / NM_001190274.2; = p.C99= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs747367036, COSV57015821; called by muse, mutect2, varscan2
- ORM1 | c.282C>G p.T94= | Silent (SNP) | VAF 30/270 reads (11%) | catalogued as COSV52279823; called by muse, mutect2, varscan2
- RANBP6 | c.525G>A p.R175= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- TIFAB | c.438C>T p.D146= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs377099358; called by muse, mutect2, varscan2
- TIMMDC1 | c.24G>T p.P8= | Silent (SNP) | VAF 78/184 reads (42%) | called by muse, mutect2, varscan2
- H4C5 | c.-1C>A | 5'UTR (SNP) | VAF 51/125 reads (41%) | catalogued as COSV100747949; called by muse, mutect2, varscan2
- MACF1 | c.15832-9072C>G | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57132569; called by muse, varscan2
